ALCHEMIST case ALCH-B0CY — Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial (ALCHEMIST-ALCH)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/8ac48816-2423-49e6-992d-38fa796f1b67

Demographics
Sex at birth: male.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: Age at diagnosis: 81.5 years (29,774 days).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ALCH-B0CY-NB1-A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Fresh.
- Sample ALCH-B0CY-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ALCH-B0CY-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 33; Percent tumor nuclei: 60; Percent normal cells: 45; Percent necrosis: 6; Percent stromal cells: 16; Percent lymphocyte infiltration: 8; Percent monocyte infiltration: 4; Percent neutrophil infiltration: 4.
